Gene-level copy-number profile of specimen HCM-STAN-0846-C20-85A from HCMI case HCM-STAN-0846-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,938 days).
Specimen HCM-STAN-0846-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8336d44-0a9b-4ec6-a9dc-90ebb0a4ea12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0846-C20-11D (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/0784642c-cd89-4fd2-9bb5-22c59aa01dd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 11,306; copy number 2: 42,782; copy number 3: 3,453; copy number 4: 714; copy number 5: 100; copy number 6: 2; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,327,350–235,344,532, 1 gene (within-gene range 0–1): GGPS1.
- chr1:235,336,806–235,362,540, 2 genes: AL391994.1, AL357556.1.
- chr22:40,951,347–41,045,591, 2 genes: RBX1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 102 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,072,013–156,082,465, 1 gene, copy number 6: MEX3A.
- chr1:204,707,320–204,707,430, 1 gene, copy number 5: RNA5SP75.
- chr5:795,606–850,986, 2 genes, copy number 5 (within-gene range 3–5): ZDHHC11, SPCS2P3.
- chr9:136,375,577–136,400,168, 1 gene, copy number 7: SNAPC4.
- chr9:136,428,619–136,439,845, 1 gene, copy number 6: INPP5E.
- chr12:114,238,970–114,241,770, 1 gene, copy number 5: LINC02459.
- chr15:96,772,005–96,783,312, 1 gene, copy number 5: SPATA8-AS1.
- chr20:39,757,202–40,698,616, 7 genes, copy number 5: AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1.
- chr20:46,345,980–46,736,347, 14 genes, copy number 5: SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10.
- chr20:57,561,080–57,568,121, 1 gene, copy number 5: PCK1.
- chr20:59,123,381–62,776,996, 72 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,306. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
